Gene-level copy-number profile of tumor specimen TCGA-EY-A72D-01A from TCGA case TCGA-EY-A72D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 87.1 years (31,818 days).
Specimen TCGA-EY-A72D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.93de183e-0225-4aea-8a8d-c745b27ece86.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A72D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/20f28970-9401-4c26-8ee2-3ae9493f3842

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,573; copy number 2: 29,649; copy number 3: 15,584; copy number 4: 8,829; copy number 5: 2,303; copy number 6: 510; copy number 8: 60; copy number 9: 37; copy number 10: 184; copy number 12: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A72D-01A-12D-A34P-01): tumor purity 0.82, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,163 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:217,631,324–221,554,314, 69 genes, copy number 6–8 (broad region; genes not listed).
- chr1:223,109,404–223,188,154, 3 genes, copy number 5: TLR5, AL359979.2, AL359979.1.
- chr2:38,814–6,511,839, 89 genes, copy number 5–6 (broad region; genes not listed).
- chr4:153,633,692–159,401,246, 110 genes, copy number 5–10 (broad region; genes not listed).
- chr4:165,684,639–169,270,956, 32 genes, copy number 5 (within-gene range 1–5): LINC01179, TLL1, RNA5SP170, Y_RNA, AC097487.1, SPOCK3, RNA5SP171, AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1.
- chr7:53,655,508–55,878,164, 49 genes, copy number 5: LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.
- chr8:40,530,590–46,550,802, 85 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:49,817,586–56,253,372, 90 genes, copy number 5–8 (broad region; genes not listed).
- chr8:59,455,885–86,818,558, 420 genes, copy number 5 (broad region; genes not listed).
- chr8:114,282,067–120,813,359, 61 genes, copy number 5 (broad region; genes not listed).
- chr11:67,518,912–71,639,769, 131 genes, copy number 6–10 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5–12 (broad region; genes not listed).
- chr14:28,264,390–33,804,176, 85 genes, copy number 6 (broad region; genes not listed).
- chr14:40,267,283–40,905,513, 2 genes, copy number 5 (within-gene range 4–5): AL049828.2, AL390800.1.
- chr15:19,878,555–20,359,166, 24 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.2, AC026495.1.
- chr15:68,483,202–72,798,199, 100 genes, copy number 5 (broad region; genes not listed).
- chr15:73,051,710–73,305,205, 1 gene, copy number 5 (within-gene range 1–5): NEO1.
- chr15:73,255,334–75,455,842, 94 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:93,177,269–94,726,519, 23 genes, copy number 6–9: AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852, AC009432.1, AC022308.1.
- chr15:94,855,586–94,857,011, 1 gene, copy number 6: AC107976.1.
- chr15:95,638,316–101,933,350, 149 genes, copy number 6–12 (broad region; genes not listed).
- chr16:61,638,233–62,187,646, 6 genes, copy number 5: AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P.
- chr16:66,301,809–67,416,833, 66 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:5,840,695–7,301,153, 31 genes, copy number 6: MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1.
- chr19:32,025,808–34,471,251, 67 genes, copy number 5 (broad region; genes not listed).
- chr19:43,303,171–43,614,498, 18 genes, copy number 6: CEACAMP4, AC005392.2, CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5.
- chr20:30,214,765–32,961,609, 85 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:46,709,649–64,313,132, 421 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:26,378,552–26,471,698, 1 gene, copy number 5 (within-gene range 2–5): AP001596.1.

Autosomal genes at a single copy (total copy number 1): 2,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
